Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-AA6G, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-AA6G-01A (Primary Tumor).

ICD-C-3
Adenocarcinoma, intestinal
814413
Site: Cardia NOS
C16.0
J23/2014

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Cardia)

"Product of esophagogastrectomy":

- . Moderately differentiated invasive and ulcerated adenocarcinoma of Laurén's intestinal type
- . Neoplasia size: 5.0 x 4.0 x 1.4cm
- . Location: cardia
- . Depth of infiltration: up to subserosa
- . Sanguineous vascular invasion: not detected
- . Lymphatic vascular invasion: present
- . Perineural invasion: not detected
- . Adjacent gastric mucosa: moderate chronic inactive gastritis
- . Esophageal adjacent mucosa: moderate chronic esophagitis
- . Surgical margins free of neoplastic involvement
- . 19 lymph nodes were dissected from peri-gastric fat, all free of tumor (0/19), distributed as follows:

- Chain 1 - right paracardic: 0/2
- Chain 2 - left paracardic: 0/3. Presence of neoplastic infiltration in the adipose tissue
- Chain 3 - lesser curvature: 0/5
- Chain 7 - left gastric artery: 0/2
- Chain 9 - celiac trunk: 0/3
- Chain 110 - inferior paraesophageal: 0 4

"Greater omentum":

- . Free of neoplasia

"Esophageal margin":

- . Free of neoplasia

Criteria	hw 12/23/13	Yes	No

Source: NCI Genomic Data Commons file ac6d8aa6-7a55-4fa5-bc9f-58742b6c1329 (TCGA-VQ-AA6G.03985625-8D3E-4D02-97B4-C349D272107C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).